Somatic mutation profile of tumor specimen HCM-BROD-0196-C71-01A (aliquot HCM-BROD-0196-C71-01A-11D-A786-36) from HCMI case HCM-BROD-0196-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.9 years (21,887 days).
Specimen HCM-BROD-0196-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b98a1d8-78be-4c51-b8d4-a3d211bade0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0196-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0196-C71-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd8dcd78-24a3-4e4c-a4dd-a512c439bdb0

The open-access MAF lists 77 somatic variants for this specimen: 51 protein-altering or splice-affecting, 12 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 12, RNA 5, Intron 5, Nonsense Mutation 3, 3'UTR 2, 5'Flank 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 5001/8578 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 2665/8689 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDH7 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.765); catalogued as rs1420186009, COSV59886253; called by muse, mutect2
- DAZAP2 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 107/207 reads (52%) | catalogued as COSV101331557; called by muse, mutect2, varscan2
- FKBP9 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs762749018, COSV54227811, COSV54229232; called by muse, mutect2, varscan2
- GLT1D1 | c.965T>G p.M322R (on ENST00000442111 / NM_001366889.1; = p.M242R on NM_144669.3) | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1327733744; called by muse, mutect2, varscan2
- GPSM2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 108/297 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs757559568, COSV51443037, COSV51443915; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHE | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 244/567 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as rs377424997; called by muse, mutect2, varscan2
- IL1R1 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 118/264 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.024); catalogued as rs749524190, COSV52105792; called by muse, mutect2, varscan2
- KRIT1 | c.413T>C p.I138T | Missense Mutation (SNP) | VAF 130/523 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs1172939308, CS108376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN5 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 137/287 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1358755376, COSV53254064; called by muse, mutect2, varscan2
- MMP7 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 123/314 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as rs773617283, COSV52771873; called by muse, mutect2, varscan2
- NDEL1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765053880, COSV55326803; called by muse, mutect2, varscan2
- OR5F1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs190524347, COSV53546231; called by muse, mutect2, varscan2
- PCLO | c.11395C>T p.R3799* | Nonsense Mutation (SNP) | VAF 141/552 reads (26%) | catalogued as COSV61656825; called by muse, mutect2, varscan2
- PTEN | c.492+1G>A p.X164_splice | Splice Site (SNP) | VAF 89/118 reads (75%) | catalogued as CD020869, COSV64293587, COSV64301805, COSV64306784; called by muse, mutect2, varscan2
- SCN4A | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 224/652 reads (34%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs756852107, COSV101438326; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMIM21 | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1222210444; called by muse, mutect2, varscan2
- SORCS3 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 265/314 reads (84%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs979252992; called by muse, mutect2, varscan2
- SPTA1 | c.3767C>A p.A1256D | Missense Mutation (SNP) | VAF 208/467 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); catalogued as COSV63760259; called by muse, mutect2, varscan2
- TEKT2 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 359/766 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375676685, COSV99255507; called by muse, mutect2, varscan2
- XIRP2 | c.9385C>T p.R3129C (on ENST00000628543; = p.R3304C on NM_152381.6) | Missense Mutation (SNP) | VAF 116/330 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs374718160, COSV99748747; called by muse, mutect2, varscan2
- ZNF628 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 22/776 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs1445004685; called by muse, mutect2
- ASMT | c.487G>C p.V163L | Missense Mutation (SNP) | VAF 502/1215 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CNTNAP2 | c.2216C>A p.P739H | Missense Mutation (SNP) | VAF 372/1222 reads (30%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CSMD3 | c.5311G>A p.G1771S (on ENST00000297405 / NM_001363185.1; = p.G1667S on NM_052900.3) | Missense Mutation (SNP) | VAF 49/380 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNK1E | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHX4 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 76/96 reads (79%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- EPN1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- ETS2 | c.742A>C p.S248R | Missense Mutation (SNP) | VAF 295/736 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- FAM171A2 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2
- GYPA | c.144C>A p.H48Q | Missense Mutation (SNP) | VAF 137/371 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HIC2 | c.636A>C p.Q212H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDNK | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 53/297 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- JAKMIP3 | c.2041A>G p.R681G | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF26B | c.529T>A p.W177R | Missense Mutation (SNP) | VAF 84/409 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LGR6 | c.2507A>G p.D836G (on ENST00000367278 / NM_001017403.1; = p.D784G on NM_021636.3) | Missense Mutation (SNP) | VAF 124/229 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- MATR3 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 135/295 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MINDY3 | c.418G>C p.A140P | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MRPS23 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 127/305 reads (42%) | called by muse, mutect2, varscan2
- NPY5R | c.843C>A p.F281L | Missense Mutation (SNP) | VAF 106/227 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDZD8 | c.1611A>G p.I537M | Missense Mutation (SNP) | VAF 162/184 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- PI4KA | c.437A>C p.D146A | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PRAMEF17 | c.821T>A p.I274K | Missense Mutation (SNP) | VAF 110/534 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PRRT2 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 195/480 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPS21 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SORCS1 | c.680A>G p.K227R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SRPK2 | c.926C>G p.A309G | Missense Mutation (SNP) | VAF 96/755 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF1 | c.1192G>A p.G398R (on ENST00000373790 / NM_138923.4; = p.G419R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/161 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TAOK3 | c.674A>G p.N225S | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- ZNF98 | c.1247G>T p.S416I | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by mutect2, varscan2
- DCLK1 | c.87C>T p.G29= | Silent (SNP) | VAF 197/429 reads (46%) | called by muse, mutect2, varscan2
- FICD | c.1251C>T p.F417= | Silent (SNP) | VAF 212/519 reads (41%) | catalogued as COSV99934125; called by muse, mutect2, varscan2
- GOLGA6C | c.573C>T p.S191= | Silent (SNP) | VAF 322/1766 reads (18%) | called by muse, mutect2, varscan2
- KRTAP20-2 | c.78T>C p.C26= | Silent (SNP) | VAF 353/821 reads (43%) | called by muse, mutect2, varscan2
- MGAM2 | c.1248C>T p.Y416= | Silent (SNP) | VAF 78/297 reads (26%) | catalogued as rs549297711; called by muse, mutect2, varscan2
- MUC16 | c.27513G>A p.S9171= | Silent (SNP) | VAF 215/433 reads (50%) | catalogued as rs372068481; called by muse, mutect2, varscan2
- PNCK | c.592C>T p.L198= (on ENST00000340888 / NM_001366975.1; = p.L281= on NM_001039582.3) | Silent (SNP) | VAF 100/110 reads (91%) | called by muse, mutect2, varscan2
- PPP1R3A | c.162G>T p.L54= | Silent (SNP) | VAF 49/366 reads (13%) | called by muse, mutect2, varscan2
- TNFRSF8 | c.1485G>A p.S495= | Silent (SNP) | VAF 191/435 reads (44%) | catalogued as rs777110831; called by muse, mutect2, varscan2
- TRPV5 | c.2160G>A p.E720= | Silent (SNP) | VAF 151/493 reads (31%) | catalogued as rs1202025630, COSV54690696; called by muse, mutect2, varscan2
- TTN | c.38121C>T p.H12707= (on ENST00000591111; = p.H5283= on NM_003319.4) | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as rs1060503970; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF304 | c.474T>C p.C158= | Silent (SNP) | VAF 105/251 reads (42%) | called by muse, mutect2, varscan2
- AC079612.1 | n.474G>T | RNA (SNP) | VAF 98/639 reads (15%) | called by muse, mutect2, varscan2
- CCDC39 | c.2266-545C>A | Intron (SNP) | VAF 61/133 reads (46%) | called by muse, mutect2, varscan2
- CINP | c.-15A>G | 5'UTR (SNP) | VAF 122/288 reads (42%) | catalogued as rs1476254135; called by muse, mutect2, varscan2
- CLK2P1 | n.787C>T | RNA (SNP) | VAF 346/1275 reads (27%) | catalogued as rs1360985658; called by muse, mutect2, varscan2
- CRB1 | c.*1G>A | 3'UTR (SNP) | VAF 109/664 reads (16%) | catalogued as rs776757972; called by muse, mutect2, varscan2
- DENND5B | c.128-4599T>A | Intron (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- GCGR | c.658-22G>A | Intron (SNP) | VAF 250/564 reads (44%) | catalogued as rs774870069; called by muse, mutect2, varscan2
- HMGB1P1 | n.58G>A | RNA (SNP) | VAF 124/318 reads (39%) | called by muse, mutect2, varscan2
- LRRK2 | c.3496+1758G>T | Intron (SNP) | VAF 101/205 reads (49%) | called by muse, mutect2, varscan2
- MIR206 | n.19G>T | RNA (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- MIR9-1 | n.12_14del | RNA (DEL) | VAF 62/186 reads (33%) | called by pindel, varscan2
- PREX1 | c.*25C>T | 3'UTR (SNP) | VAF 51/224 reads (23%) | catalogued as rs769863202; called by muse, mutect2, varscan2
- PXN | c.832-1175C>T | Intron (SNP) | VAF 28/67 reads (42%) | catalogued as rs766168753; called by muse, mutect2, varscan2
- RPL37P13 | chr2:62511822 T>A | 5'Flank (SNP) | VAF 110/262 reads (42%) | called by muse, mutect2, varscan2
